Somatic mutation profile of tumor specimen MMRF_2107_1_BM_CD138pos (aliquot MMRF_2107_1_BM_CD138pos_T1_KHS5U_L08134) from MMRF case MMRF_2107, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.6 years (23,217 days).
Specimen MMRF_2107_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1835fbf6-16bb-46b7-b6ef-e3a1596541d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2107_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2107_1_PB_Whole_C2_KHS5U_L08135; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddb68307-c5fc-4b69-bf9f-cdb5b82fb09f

The open-access MAF lists 132 somatic variants for this specimen: 42 protein-altering or splice-affecting, 16 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 39, Missense Mutation 33, Silent 16, Intron 16, 5'UTR 11, 3'Flank 5, Frame Shift Del 3, Frame Shift Ins 2, Nonsense Mutation 2, 5'Flank 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB13 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as rs865983389; called by muse, mutect2
- BACE2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 59/83 reads (71%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.946); catalogued as rs549639705, COSV100161293; called by muse, mutect2, varscan2
- ENPEP | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 89/94 reads (95%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs745497811, COSV54456771; called by muse, mutect2, varscan2
- EPHB2 | c.1843G>A p.E615K (on ENST00000400191 / NM_001309193.2; = p.E616K on NM_004442.7) | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV65863907; called by muse, mutect2, varscan2
- KCNS2 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771255852, COSV54638164; called by muse, mutect2, varscan2
- LRWD1 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 201/300 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756118406, COSV52960688; called by muse, mutect2, varscan2
- MYT1L | c.2681T>C p.L894P | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101220770; called by muse, mutect2, varscan2
- NUDT22 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as rs762609249; called by muse, mutect2, varscan2
- PPP1R12C | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440705985, COSV99670027; called by muse, mutect2, varscan2
- SH3RF2 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.986); catalogued as rs753961992; called by muse, mutect2, varscan2
- TBC1D4 | c.14G>C p.S5T | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.827); catalogued as rs776733868, COSV66492737; called by muse, mutect2, varscan2
- TEX9 | c.564T>G p.I188M | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.19); catalogued as rs774477540; called by muse, mutect2, varscan2
- TTN | c.42088G>A p.D14030N (on ENST00000591111; = p.D6606N on NM_003319.4) | Missense Mutation (SNP) | VAF 121/426 reads (28%) | PolyPhen probably damaging (0.998); catalogued as rs748275289, COSV59871715; called by muse, mutect2, varscan2
- ZNF19 | c.322T>C p.S108P | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.605); catalogued as rs867891952; called by muse, mutect2, varscan2
- ADGRF1 | c.2147T>C p.I716T | Missense Mutation (SNP) | VAF 97/320 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ADGRG4 | c.4874T>C p.V1625A | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- ANO5 | c.2671A>C p.N891H | Missense Mutation (SNP) | VAF 78/127 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- BARHL1 | c.373_375del p.P125del | In Frame Del (DEL) | VAF 34/163 reads (21%) | called by mutect2, pindel, varscan2
- C10orf67 | c.605C>T p.T202I (on ENST00000636213 / NM_001365862.2; = p.T170I on NM_001351306.2) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- C16orf70 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD7 | c.4726T>G p.F1576V | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CLHC1 | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CUBN | c.10168T>C p.Y3390H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- EIF2S1 | c.133A>G p.M45V | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ERICH6B | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM47B | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 37/39 reads (95%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- FANCL | c.797del p.K266Sfs*2 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- IGHA1 | c.489_492del p.P164Qfs*51 | Frame Shift Del (DEL) | VAF 14/19 reads (74%) | called by mutect2, pindel*, varscan2
- IGHA1 | c.325_328dup p.P110Hfs*68 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- JUNB | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 106/229 reads (46%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1328 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MUC16 | c.11237C>T p.S3746L | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NBEA | c.2650A>C p.R884= | Splice Region (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- PCDH7 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RENBP | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 29/29 reads (100%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEMA3E | c.1000A>C p.N334H | Missense Mutation (SNP) | VAF 77/115 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SMARCA1 | c.2623T>G p.Y875D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2
- STIP1 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF160 | c.2112_2133del p.Y705Kfs*9 | Frame Shift Del (DEL) | VAF 103/211 reads (49%) | called by mutect2, pindel, varscan2
- ZNF451 | c.2101dup p.T701Nfs*2 | Frame Shift Ins (INS) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- ZNF879 | c.1590C>G p.H530Q | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS15 | c.2340C>T p.T780= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as rs750849392; called by muse, mutect2, varscan2
- ATP10A | c.574C>T p.L192= | Silent (SNP) | VAF 74/190 reads (39%) | called by muse, mutect2, varscan2
- ATP8A1 | c.375A>G p.K125= | Silent (SNP) | VAF 39/41 reads (95%) | catalogued as COSV100047535; called by muse, mutect2, varscan2
- BPIFA3 | c.55T>C p.L19= | Silent (SNP) | VAF 91/212 reads (43%) | called by muse, mutect2, varscan2
- CD34 | c.480C>T p.P160= | Silent (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
- CEP152 | c.3477G>A p.K1159= | Silent (SNP) | VAF 16/143 reads (11%) | catalogued as rs955334640; called by muse, mutect2, varscan2
- CTLA4 | c.354A>C p.G118= | Silent (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- IGLV3-1 | c.72T>C p.T24= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs191429645; called by muse, varscan2
- NAGLU | c.1674C>T p.Y558= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs762031686, CM118225; called by muse, mutect2, varscan2
- PDIA4 | c.22C>T p.L8= | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- PIP4K2C | c.405A>G p.E135= | Silent (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- RBM12 | c.1599A>G p.L533= | Silent (SNP) | VAF 29/564 reads (5%) | called by muse, mutect2
- RFTN1 | c.747T>G p.L249= | Silent (SNP) | VAF 62/201 reads (31%) | called by muse, varscan2
- TG | c.1230C>A p.P410= | Silent (SNP) | VAF 45/111 reads (41%) | called by muse, mutect2, varscan2
- THSD7B | c.2676T>C p.S892= | Silent (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- ZNRF3 | c.1752C>T p.S584= (on ENST00000544604 / NM_001206998.2; = p.S484= on NM_032173.3) | Silent (SNP) | VAF 178/353 reads (50%) | called by muse, mutect2, varscan2
- AADACL3 | c.*1409G>A | 3'UTR (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- AC011840.1 | n.632G>A | RNA (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- ACACB | c.5023-53G>A | Intron (SNP) | VAF 9/182 reads (5%) | called by muse, mutect2
- ACTR3B | c.*334G>A | 3'UTR (SNP) | VAF 26/76 reads (34%) | catalogued as rs1003598716; called by muse, mutect2, varscan2
- AFAP1L1 | c.*1015C>T | 3'UTR (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- ANKRD26 | c.-133G>C | 5'UTR (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- APBB1 | c.1389-20A>T | Intron (SNP) | VAF 104/292 reads (36%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021445 C>T | 5'Flank (SNP) | VAF 50/90 reads (56%) | catalogued as COSV55846302, COSV55847851, COSV55851309; called by muse, mutect2, varscan2
- BMPR1B | chr4:95156523 A>T | 3'Flank (SNP) | VAF 23/24 reads (96%) | called by muse, mutect2, varscan2
- BRWD1 | c.6571+385C>T | Intron (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
- C1QL2 | c.*177G>A | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- C2orf76 | c.-13+151T>G | Intron (SNP) | VAF 133/225 reads (59%) | called by muse, mutect2, varscan2
- CACNA2D2 | chr3:50362951 A>G | 3'Flank (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- CDYL | c.-11G>A | 5'UTR (SNP) | VAF 112/534 reads (21%) | catalogued as rs368064519; called by muse, mutect2
- CRHR2 | c.1095+271G>A | Intron (SNP) | VAF 67/264 reads (25%) | catalogued as rs1312121742; called by muse, mutect2, varscan2
- CSNK1A1 | c.*1847C>T | 3'UTR (SNP) | VAF 37/166 reads (22%) | called by muse, mutect2, varscan2
- CYP26B1 | c.-43C>A | 5'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- CYYR1 | c.*1236A>G | 3'UTR (SNP) | VAF 81/130 reads (62%) | called by muse, mutect2, varscan2
- DDX5 | c.44+292A>G | Intron (SNP) | VAF 117/376 reads (31%) | called by muse, mutect2, varscan2
- DERL2 | c.*2514dup | 3'UTR (INS) | VAF 36/128 reads (28%) | called by mutect2, pindel, varscan2
- DNASE1 | chr16:3662855 G>A | 3'Flank (SNP) | VAF 48/99 reads (48%) | catalogued as rs1457293852; called by muse, mutect2, varscan2
- ERGIC1 | c.375+3185A>G | Intron (SNP) | VAF 48/112 reads (43%) | called by muse, mutect2
- EZR | c.12+65C>G | Intron (SNP) | VAF 50/141 reads (35%) | called by muse, varscan2
- EZR | c.-61T>G | 5'UTR (SNP) | VAF 102/314 reads (32%) | called by muse, varscan2
- FAM102B | c.*2373G>C | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- FBXO22 | c.*1205G>A | 3'UTR (SNP) | VAF 34/182 reads (19%) | called by muse, mutect2, varscan2
- FUT10 | c.*1536del | 3'UTR (DEL) | VAF 33/48 reads (69%) | called by mutect2, pindel, varscan2
- GANC | c.*1120A>G | 3'UTR (SNP) | VAF 26/736 reads (4%) | called by muse, mutect2
- HFE | c.*3205C>T | 3'UTR (SNP) | VAF 38/57 reads (67%) | called by muse, mutect2, varscan2
- HPSE | c.*1636A>C | 3'UTR (SNP) | VAF 56/56 reads (100%) | called by muse, mutect2, varscan2
- IFT140 | c.-192G>A | 5'UTR (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- IGLL5 | c.-169T>A | 5'UTR (SNP) | VAF 52/80 reads (65%) | called by muse, varscan2
- IGLL5 | c.-99G>A | 5'UTR (SNP) | VAF 46/76 reads (61%) | catalogued as rs192387679, COSV73249145; called by muse, varscan2
- LRRN4 | c.*152T>C | 3'UTR (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- LTB | c.163-154C>G | Intron (SNP) | VAF 78/240 reads (33%) | called by muse, mutect2, varscan2
- LYRM9 | c.220-31C>A | Intron (SNP) | VAF 33/51 reads (65%) | called by muse, mutect2, varscan2
- MAB21L1 | c.*376A>C | 3'UTR (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- MASP1 | c.-84G>A | 5'UTR (SNP) | VAF 95/263 reads (36%) | catalogued as rs755563783, COSV99397473; called by muse, mutect2, varscan2
- MATR3 | c.-462+58C>T | Intron (SNP) | VAF 128/254 reads (50%) | called by muse, varscan2
- MIR5195 | chr14:106851235 T>C | 5'Flank (SNP) | VAF 60/143 reads (42%) | catalogued as rs561199976; called by muse, mutect2, varscan2
- MOG | c.*429C>T | 3'UTR (SNP) | VAF 148/223 reads (66%) | catalogued as rs770558135; called by muse, mutect2, varscan2
- MYO1E | c.-38C>T | 5'UTR (SNP) | VAF 34/94 reads (36%) | catalogued as rs1001549188; called by muse, mutect2, varscan2
- NR2F2 | c.*1586del | 3'UTR (DEL) | VAF 52/128 reads (41%) | called by mutect2, varscan2
- NXPH1 | c.*385G>A | 3'UTR (SNP) | VAF 17/128 reads (13%) | catalogued as rs1405085480; called by muse, mutect2, varscan2
- PCF11 | c.*228A>C | 3'UTR (SNP) | VAF 39/62 reads (63%) | called by muse, mutect2, varscan2
- PGAP4 | c.-8T>C | 5'UTR (SNP) | VAF 31/69 reads (45%) | catalogued as rs764315878; called by muse, mutect2, varscan2
- PGC | c.648-340C>T | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- PIK3CG | chr7:106907219 C>G | 3'Flank (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- PITX1 | c.*4C>T | 3'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- PTCD1 | c.*1603C>T | 3'UTR (SNP) | VAF 54/203 reads (27%) | catalogued as rs576428593; called by muse, mutect2, varscan2
- PTDSS2 | c.*645G>A | 3'UTR (SNP) | VAF 97/286 reads (34%) | catalogued as rs1030397124; called by muse, mutect2, varscan2
- PURA | c.*1605A>C | 3'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- RET | c.*835G>A | 3'UTR (SNP) | VAF 45/79 reads (57%) | catalogued as rs1404429349; called by muse, mutect2, varscan2
- S1PR2 | c.-43+784C>T | Intron (SNP) | VAF 49/106 reads (46%) | catalogued as rs538224926, COSV73912640, COSV73912837; called by muse, mutect2, varscan2
- SELENOF | c.*198T>C | 3'UTR (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- STARD8 | c.-7-1019C>T | Intron (SNP) | VAF 52/60 reads (87%) | catalogued as rs773128718, COSV52928878; called by muse, mutect2, varscan2
- TCAF1 | c.*2423T>G | 3'UTR (SNP) | VAF 41/351 reads (12%) | called by muse, mutect2, varscan2
- TEX19 | c.*81C>T | 3'UTR (SNP) | VAF 25/105 reads (24%) | catalogued as rs935634766, COSV100331015; called by muse, mutect2, varscan2
- TMEM236 | c.*2934T>A | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- TMEM236 | c.*3955C>T | 3'UTR (SNP) | VAF 75/165 reads (45%) | called by muse, mutect2, varscan2
- TMEM40 | chr3:12734083 del A | 3'Flank (DEL) | VAF 27/45 reads (60%) | catalogued as rs531847151; called by mutect2, varscan2
- TMEM43 | c.*537del | 3'UTR (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- TMOD2 | c.*7444A>C | 3'UTR (SNP) | VAF 40/232 reads (17%) | called by muse, mutect2, varscan2
- TRAM2 | c.*2303T>C | 3'UTR (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- TRAM2 | c.*2302C>G | 3'UTR (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- UBXN4 | c.*1975_*1984delinsAGTACATGGT | 3'UTR (ONP) | VAF 10/91 reads (11%) | called by pindel, varscan2*
- VEGFD | c.*179T>A | 3'UTR (SNP) | VAF 17/18 reads (94%) | called by muse, mutect2, varscan2
- VNN3 | c.*255G>C | 3'UTR (SNP) | VAF 165/494 reads (33%) | called by muse, mutect2, varscan2
- WASHC4 | c.2514+44del | Intron (DEL) | VAF 46/117 reads (39%) | called by mutect2, pindel, varscan2
- ZDHHC7 | c.*2094T>A | 3'UTR (SNP) | VAF 32/68 reads (47%) | called by muse, varscan2
- ZNF350 | c.-99G>T | 5'UTR (SNP) | VAF 57/431 reads (13%) | called by muse, mutect2, varscan2
- ZNF385D | c.*425del | 3'UTR (DEL) | VAF 23/68 reads (34%) | catalogued as rs113101913, COSV99872942; called by mutect2, varscan2
- ZNF704 | c.*9635C>T | 3'UTR (SNP) | VAF 23/56 reads (41%) | catalogued as rs957469049; called by muse, mutect2, varscan2
- ZNF879 | c.-35-289C>T | Intron (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
